Gene-level copy-number profile of tumor specimen ALCH-AEE1-TTP1-A from ALCHEMIST case ALCH-AEE1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.2 years (23,812 days).
Specimen ALCH-AEE1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6b522f2-68f8-4892-a6a3-76b340ebe292.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEE1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/2a17a440-2414-4033-bb9c-78b1d0047f8f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,066; copy number 2: 53,763; copy number 3: 2,554; copy number 4: 7; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,915,153–143,976,734, 2 genes: PLEC, MIR661.
- chr17:81,197,393–81,200,288, 1 gene (within-gene range 0–2): AC027601.2.
- chr20:63,558,086–63,574,239, 1 gene: HELZ2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,459,455–130,509,707, 2 genes, copy number 5: POTEI, RNU6-473P.

Autosomal genes at a single copy (total copy number 1): 2,066. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
